Somatic mutation profile of tumor specimen TCGA-31-1950-01A (aliquot TCGA-31-1950-01A-01W-0699-08) from TCGA case TCGA-31-1950, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.9 years (28,100 days).
Specimen TCGA-31-1950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00314e2b-494f-4434-8ddf-b8e5c3bc5b3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-31-1950-10A (Blood Derived Normal), aliquot TCGA-31-1950-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/499c41f6-e04c-44a0-8d50-fef98bbb6fa5

The open-access MAF lists 65 somatic variants for this specimen: 42 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Intron 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894253, CM108760, CM970812, COSV60661395, COSV60662134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 94/223 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAT1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV57187170; called by muse, mutect2, varscan2
- ADCY8 | c.3686C>A p.T1229N | Missense Mutation (SNP) | VAF 37/502 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99651308; called by muse, mutect2
- ADPRS | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV99255418; called by muse, mutect2
- ARHGEF15 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs775334628, COSV62725623; called by muse, mutect2, varscan2
- ATXN2 | c.3185A>G p.H1062R (on ENST00000550104; = p.H902R on NM_002973.4) | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV66484144; called by muse, mutect2, varscan2
- C1orf87 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs771976072, COSV64597585; called by muse, varscan2
- CCDC6 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.1); catalogued as COSV54057553; called by muse, mutect2, varscan2
- CDC37 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55768196; called by muse, mutect2, varscan2
- CLTCL1 | c.4073G>A p.W1358* | Nonsense Mutation (SNP) | VAF 29/190 reads (15%) | catalogued as rs1555935639, COSV54233405; called by muse, mutect2, varscan2
- COL5A1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs367905915; ClinVar: uncertain significance; called by mutect2, varscan2
- CSKMT | c.545C>A p.S182* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as rs1341148702, COSV100649041, COSV63472913; called by muse, mutect2
- CTAG2 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55995633, COSV99908914; called by muse, varscan2
- DIO2 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV101375835; called by muse, mutect2
- DLGAP1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1258270976, COSV59814670; called by muse, mutect2, varscan2
- ESF1 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as COSV52522135; called by muse, mutect2, varscan2
- GALNT13 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs747061747, COSV67226297; called by muse, mutect2, varscan2
- GRM1 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.054); catalogued as COSV51181843; called by muse, mutect2, varscan2
- HSPG2 | c.9017C>T p.T3006I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs376414322; called by muse, mutect2, varscan2
- IL10RB | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV51616312; called by muse, mutect2, varscan2
- ITSN1 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV66084057; called by muse, mutect2, varscan2
- MAS1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs757715611, COSV53121480; called by muse, mutect2, varscan2
- MYOF | c.4931G>A p.R1644Q | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372110838; called by muse, mutect2, varscan2
- NINL | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV54004557; called by muse, mutect2, varscan2
- NOS2 | c.1554G>T p.L518F | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100569541; called by muse, mutect2
- NUSAP1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV52971784; called by muse, mutect2, varscan2
- OPN4 | c.801G>A p.R267= | Splice Region (SNP) | VAF 9/57 reads (16%) | catalogued as COSV54117216; called by muse, mutect2, varscan2
- OR5T2 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100506860; called by muse, mutect2
- PAX3 | c.375C>G p.N125K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV51340804; called by muse, mutect2, varscan2
- PROS1 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs200771229, COSV67775909; called by muse, mutect2, varscan2
- RB1CC1 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV50273186; called by muse, mutect2
- RPRD2 | c.2378G>A p.G793D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as COSV64821451; called by muse, mutect2, varscan2
- RUNDC3B | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99712456; called by muse, mutect2
- STK38 | c.1076+1G>A p.X359_splice | Splice Site (SNP) | VAF 46/260 reads (18%) | catalogued as COSV57709393; called by muse, mutect2, varscan2
- STUM | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64683457, COSV64684668; called by muse, mutect2, varscan2
- SVOPL | c.1259C>G p.A420G (on ENST00000419765; = p.A268G on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV55992540; called by muse, mutect2, varscan2
- TMEM94 | c.1625A>C p.Y542S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58597306; called by muse, varscan2
- WNK3 | c.1611A>C p.E537D | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100671009; called by muse, mutect2
- ZFP42 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV58818042; called by muse, mutect2, varscan2
- ZNF479 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58638365; called by muse, mutect2, varscan2
- LILRB3 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- CALCOCO1 | c.735G>A p.L245= | Silent (SNP) | VAF 125/909 reads (14%) | catalogued as rs1184415954, COSV100017201; called by muse, mutect2, varscan2
- CHIT1 | c.303C>T p.F101= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1287331665, COSV55147728; called by muse, varscan2
- DOCK1 | c.1143G>A p.L381= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as rs199995435, COSV99727846; called by muse, mutect2
- ERV3-1 | c.549T>C p.L183= | Silent (SNP) | VAF 106/583 reads (18%) | catalogued as COSV99275322; called by muse, mutect2, varscan2
- EVX2 | c.129G>T p.S43= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV57963924; called by muse, mutect2, varscan2
- FLII | c.2631C>T p.L877= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs754732453, COSV57498920; called by muse, mutect2
- FRMPD2 | c.2457G>A p.T819= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs148717200; called by muse, mutect2, varscan2
- GALNT14 | c.378G>A p.T126= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs200313372; called by muse, mutect2, varscan2
- KCNA5 | c.315C>A p.G105= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52906901; called by mutect2, varscan2
- MTA3 | c.537T>C p.V179= | Silent (SNP) | VAF 16/364 reads (4%) | catalogued as COSV101290705; called by muse, mutect2
- NOS3 | c.1317G>A p.G439= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV52491460; called by muse, mutect2, varscan2
- PCNT | c.1287G>C p.R429= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV64029887; called by muse, mutect2, varscan2
- PITPNM2 | c.339C>G p.T113= | Silent (SNP) | VAF 64/389 reads (16%) | catalogued as COSV54901166, COSV54903193; called by muse, mutect2, varscan2
- PPP1R13B | c.1896C>A p.S632= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99157972; called by muse, mutect2
- RBM48 | c.993T>C p.N331= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV56003072; called by muse, mutect2, varscan2
- RIPOR3 | c.2679C>T p.S893= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99246063; called by muse, mutect2
- RREB1 | c.102C>T p.G34= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs146325538; called by muse, mutect2
- SLC7A14 | c.2130C>T p.Y710= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs201486833; called by muse, mutect2, varscan2
- TMEM201 | c.840G>A p.E280= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100440314; called by muse, mutect2
- TOP1MT | c.1395C>G p.L465= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV100239290; called by muse, mutect2
- WIPF1 | c.1473A>G p.R491= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs1451007890, COSV99768219; called by muse, mutect2
- COL17A1 | c.2228-70G>A | Intron (SNP) | VAF 94/287 reads (33%) | catalogued as rs1258994058, COSV100793094; called by muse, mutect2, varscan2
- RIT2 | c.426+2843T>C | Intron (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99949868; called by muse, mutect2
